Somatic mutation profile of tumor specimen TCGA-EE-A2ME-06A (aliquot TCGA-EE-A2ME-06A-11D-A197-08) from TCGA case TCGA-EE-A2ME, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 57.7 years (21,086 days).
Specimen TCGA-EE-A2ME-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8cfe0ff8-cf0a-4618-90cc-0d412f70c202.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2ME-10A (Blood Derived Normal), aliquot TCGA-EE-A2ME-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45013b9b-1e30-4b06-be64-ce845967c984

The open-access MAF lists 28 somatic variants for this specimen: 18 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 16, Silent 10, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AK9 | c.3152C>T p.A1051V | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV58137746; called by muse, mutect2
- C12orf40 | c.941G>A p.R314K | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV61129570; called by muse, mutect2
- COL12A1 | c.5185C>T p.P1729S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); catalogued as rs1329724602, COSV59390031; called by muse, mutect2, varscan2
- COL4A5 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.966); catalogued as COSV60356504; called by muse, mutect2
- CRP | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as COSV54812667; called by muse, mutect2
- DCAF8L1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs767977769, COSV71595101; called by muse, mutect2, varscan2
- FLG2 | c.4219G>A p.G1407R | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.169); catalogued as COSV66166808, COSV66168273; called by muse, mutect2
- KLHL28 | c.1237T>G p.W413G | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61887416; called by muse, mutect2
- MARK3 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53506597; called by muse, mutect2
- MROH8 | c.1406C>T p.S469F | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.162); catalogued as COSV54117477; called by mutect2, varscan2
- MYH6 | c.4755G>A p.M1585I | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1060501427, COSV62448063; ClinVar: uncertain significance; called by muse, mutect2
- POLR3B | c.2041C>T p.P681S | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57276186; called by muse, mutect2, varscan2
- RABL6 | c.1822C>T p.P608S | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated, low confidence (0.46); PolyPhen possibly damaging (0.717); catalogued as COSV61033451; called by muse, mutect2, varscan2
- TUFT1 | c.1013T>C p.L338S | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV61947935; called by muse, mutect2
- ZFHX4 | c.5867C>T p.S1956F | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50511023; called by muse, mutect2
- PRAMEF20 | c.294G>A p.W98* | Nonsense Mutation (SNP) | VAF 21/400 reads (5%) | called by muse, mutect2
- RAPGEF3 | c.2191del p.R731Gfs*39 (on ENST00000389212; = p.R689Gfs*39 on NM_006105.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel, varscan2
- BRD1 | c.756C>T p.P252= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs538087121, COSV53454982; called by muse, mutect2, varscan2
- DNAJC25 | c.429C>T p.A143= | Silent (SNP) | VAF 14/213 reads (7%) | catalogued as COSV57956294; called by muse, mutect2
- IL2RB | c.732C>T p.L244= | Silent (SNP) | VAF 39/118 reads (33%) | catalogued as rs778519038, COSV53424778; called by muse, mutect2, varscan2
- MAP6 | c.1977G>A p.K659= | Silent (SNP) | VAF 10/132 reads (8%) | catalogued as COSV59074359; called by muse, mutect2
- NME8 | c.348G>A p.E116= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV52246916; called by muse, mutect2, varscan2
- RASD2 | c.333C>T p.R111= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as COSV53351992; called by muse, mutect2
- SLC12A9 | c.693C>T p.S231= | Silent (SNP) | VAF 16/131 reads (12%) | catalogued as rs1264560417, COSV51931465; called by muse, mutect2, varscan2
- SORBS3 | c.1773C>T p.S591= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV53551877; called by muse, mutect2
- TRAF5 | c.375C>T p.Y125= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV54821203; called by muse, mutect2
- TSGA13 | c.703C>A p.R235= | Silent (SNP) | VAF 23/346 reads (7%) | catalogued as COSV58404234; called by muse, mutect2
